Gene-level copy-number profile of tumor specimen TCGA-DX-AB3A-01A from TCGA case TCGA-DX-AB3A, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 80.0 years (29,230 days).
Specimen TCGA-DX-AB3A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.3b2424b0-1bc2-4eba-bbba-bbe6d1c1bcec.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-AB3A-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/58952ddb-275c-42a6-b3aa-13dd4b7a9cec

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 41; copy number 1: 9,995; copy number 2: 44,966; copy number 3: 2,761; copy number 4: 307; copy number 5: 275; copy number 6: 390; copy number 7: 363; copy number 8: 44; copy number 9: 58; copy number 10: 284; copy number 11: 48; copy number 12: 12; copy number 13: 11; copy number 14: 15; copy number 15: 86; copy number 16: 13; copy number 17: 37; copy number 20: 35; copy number 21: 7; copy number 22: 1; copy number 23: 4; copy number 26: 8; copy number 27: 21; copy number 28: 2; copy number 29: 4; copy number 30: 1; copy number 32: 18; copy number 38: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-AB3A-01A-11D-A416-01): tumor purity 0.87, ploidy 2.07, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 41 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:14,475–1,333,953, 30 genes: WASHC1, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, AL158832.2, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1, DMRT3, RNU6-1073P, H3P29, AL358976.1, LINC01230, DMRT2, AL356498.1, RPS27AP14, AL358934.1, RNA5SP279.
- chr9:3,824,127–4,679,502, 11 genes: GLIS3, AL137071.1, GLIS3-AS1, AL359095.1, AL162419.1, RNU6-694P, SLC1A1, SPATA6L, AL136231.1, PLPP6, CDC37L1-DT.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,738 genes in 85 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:49,257,411–54,112,519, 138 genes, copy number 6–15 (within-gene range 4–15) (broad region; genes not listed).
- chr1:58,415,384–58,931,897, 13 genes, copy number 7–12: OMA1, AL035411.3, AL035411.2, RN7SL713P, TACSTD2, AL035411.1, MYSM1, AL136985.3, JUN, LINC01135, AL136985.2, AL136985.1, LINC02777.
- chr1:59,296,638–64,693,058, 83 genes, copy number 5–10 (within-gene range 3–10) (broad region; genes not listed).
- chr1:65,792,514–66,374,579, 3 genes, copy number 8 (within-gene range 2–8): PDE4B, PDE4B-AS1, RNU4-88P.
- chr1:68,375,327–68,449,954, 3 genes, copy number 5: ELOCP18, AL139413.1, RPE65.
- chr1:72,274,552–72,753,772, 3 genes, copy number 6 (within-gene range 4–6): GDI2P2, AL513166.1, RPL31P12.
- chr1:73,635,216–75,611,116, 26 genes, copy number 5–7: LINC02238, RNA5SP50, AL591463.1, RNU4ATAC8P, LRRIQ3, FPGT, FPGT-TNNI3K, TNNI3K, AC093158.1, AC105271.1, LRRC53, ERICH3, ERICH3-AS1, AC135803.1, CRYZ, TYW3, AC133865.1, AC099786.3, AC099786.1, LHX8, AC099786.2, RNU6-622P, SLC44A5, AC093156.1, RNU6-503P, AL096829.1.
- chr1:147,419,053–147,788,953, 11 genes, copy number 8–21: OR13Z1P, Y_RNA, OR13Z2P, OR13Z3P, BCL9, AC242628.1, ACP6, AC241644.1, GJA5, AC241644.3, AC241644.2.
- chr1:153,031,203–153,226,006, 12 genes, copy number 6–26: SPRR1B, SPRR2D, SPRR2A, SPRR2B, SPRR2E, SPRR2F, SPRR2C, SPRR2G, AL161636.1, LELP1, PRR9, AL161636.2.
- chr1:153,396,591–153,541,765, 9 genes, copy number 7–23: S100A15A, S100A7A, S100A7P1, S100A7L2, S100A7, RN7SL44P, BX470102.1, S100A6, S100A5.
- chr1:159,998,651–160,070,160, 3 genes, copy number 10 (within-gene range 2–10): KCNJ10, AL513302.1, PIGM.
- chr2:174,719,908–175,034,192, 6 genes, copy number 8: H3P6, CHRNA1, CHN1, RNU6-763P, RNU6-1290P, RPL21P31.
- chr4:13,333,414–13,632,599, 9 genes, copy number 9: HSP90AB2P, RAB28, AC006445.3, LINC01097, NKX3-2, LINC01096, BOD1L1, MIR5091, AC006445.2.
- chr5:112,452,703–112,846,239, 6 genes, copy number 11 (within-gene range 2–11): HMGB3P16, AC137549.1, LINC02200, APC, CBX3P3, RNU6-482P.
- chr5:113,738,106–117,722,097, 56 genes, copy number 10–17: AC093240.1, KCNN2, RN7SKP89, AC010230.1, LINC01957, AC094104.2, AC094104.1, TRIM36, TRIM36-IT1, AC008494.2, PGGT1B, AC008494.3, AC008494.1, CCDC112, HMGN1P15, CTNNA1P1, AK3P4, AC008628.2, AC008628.1, CCT5P1, FEM1C, TICAM2, TMED7-TICAM2, AC010226.1, TMED7, AC008549.2, AC008549.1, H3P24, RNU2-49P, CDO1, ATG12, AP3S1, LINCADL, LVRN, DDX43P1, ARL14EPL, AC034236.1, AC034236.3, AC034236.2, COMMD10, RNU6-644P, HMGN2P27, AC018752.1, SEMA6A, SEMA6A-AS1, RPS14P8, SEMA6A-AS2, RPS17P2, LINC02214, AC010267.1, AC093534.1, AC093534.2, RPL35AP15, AC093295.1, LINC00992, AC114322.1.
- chr5:171,345,343–171,457,626, 9 genes, copy number 7: AC091980.1, RN7SL339P, RPSAP71, SNORA70J, RPL10P8, MIR3912, NPM1, FGF18, AC093246.1.
- chr5:173,888,349–177,300,213, 77 genes, copy number 5–16 (within-gene range 2–16) (broad region; genes not listed).
- chr6:35,650,997–36,312,229, 19 genes, copy number 9 (within-gene range 2–9): AL033519.5, AL033519.1, MIR5690, AL157823.2, ARMC12, AL157823.1, CLPSL2, CLPSL1, CLPS, LHFPL5, SRPK1, SLC26A8, DPRXP2, MAPK14, Z95152.1, MAPK13, Z84485.1, BRPF3, PNPLA1.
- chr7:49,524,208–50,843,732, 20 genes, copy number 5: AC092448.1, AC093775.1, VWC2, ZPBP, GNL2P1, AC034148.1, SPATA48, AC020743.1, AC020743.2, AC020743.3, IKZF1, AC124014.1, RNU6-1091P, FIGNL1, DDC, DDC-AS1, GRB10, AC005153.1, AC004920.1, AC009296.1.
- chr7:52,493,152–53,863,339, 15 genes, copy number 5: AC006459.1, SGO1P2, AC074397.1, POM121L12, HAUS6P1, RNF138P2, RNU1-14P, RN7SKP218, AC009468.2, AC009468.1, LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3.
- chr11:7,485,388–8,714,759, 38 genes, copy number 5–22: OLFML1, PPFIBP2, AC107884.2, CYB5R2, OVCH2, AC104237.2, AC104237.3, AC044810.3, AC104237.1, OR10AB1P, OR5P4P, AC044810.2, OR5P1P, AC044810.1, OR5P2, OR5P3, OR5E1P, RNU6-943P, OR10A6, OR10A3, NLRP10, EIF3F, COX6CP5, CASC23, TUB, AC116456.1, TUB-AS1, AC116456.2, RIC3, RIC3-DT, LMO1, STK33, AP006442.1, TRIM66, AC091053.2, RPL27A, SNORA3A, SNORA3B.
- chr12:57,546,026–57,846,729, 29 genes, copy number 20–21 (within-gene range 2–21): KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2.
- chr12:64,867,956–64,990,646, 4 genes, copy number 11 (within-gene range 2–11): RPL7P39, LINC02389, LINC02231, RNU6ATAC42P.
- chr12:65,758,020–66,276,651, 18 genes, copy number 5–21 (within-gene range 2–21): RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4, IRAK3, RBMS1P1, MIR6502, AC078889.1, PDCL3P7.
- chr12:68,610,855–68,971,570, 18 genes, copy number 32: RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1.
- chr12:69,449,470–70,243,379, 14 genes, copy number 27 (within-gene range 2–27): LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1.
- chr12:71,034,122–71,594,404, 7 genes, copy number 16–27 (within-gene range 2–27): AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1, AC078860.3, AC078860.2.
- chr12:73,115,957–73,679,296, 5 genes, copy number 5–13: AC090503.2, LINC02444, AC090503.1, AC087879.1, RNU6-1012P.
- chr12:75,649,195–75,698,816, 4 genes, copy number 15 (within-gene range 15–16): AC078820.2, RPL10P13, SNORA70, AC078820.1.
- chr17:50,627,032–52,535,701, 36 genes, copy number 5–8: AC004590.1, ABCC3, ANKRD40, AC005921.2, Y_RNA, LUC7L3, AC005921.3, ANKRD40CL, MIR8059, AC005921.4, AC005921.1, WFIKKN2, AC091062.1, RPL5P33, TOB1, TOB1-AS1, AC005920.4, AC005920.1, AC005920.3, SPAG9, AC005920.2, NME1, NME1-NME2, NME2, MBTD1, AC005839.1, AC006141.1, UTP18, LINC02071, AC005823.2, AC005823.1, LINC02073, RPL7P48, CA10, AC002090.1, LINC01982.
- chr17:54,609,249–54,771,277, 4 genes, copy number 7: AC015943.1, AC005951.1, ARL2BPP8, RN7SKP14.
- chr17:56,938,199–57,684,689, 14 genes, copy number 6 (within-gene range 4–6): COIL, AC004584.1, AC004584.2, SCPEP1, AC004584.3, RNF126P1, AC007114.1, AKAP1, AC007114.2, AC003950.1, AC091181.2, MSI2, AC091181.1, AC015883.1.
- chr17:58,345,206–66,810,743, 262 genes, copy number 6–15 (within-gene range 4–15) (broad region; genes not listed).
- chr17:69,577,251–72,237,203, 26 genes, copy number 5–10 (within-gene range 3–10): LINC01483, AC002545.1, LINC01497, Y_RNA, AC005208.1, LINC01028, KCNJ16, KCNJ2-AS1, KCNJ2, CALM2P1, AC011990.1, AC005771.1, AC007423.1, AC005181.1, CASC17, RNU7-155P, AC118653.1, MYL6P5, AC007432.1, AC005144.1, ROCR, LINC01152, AC007461.1, SOX9-AS1, LINC02097, SOX9.
- chr17:73,067,870–75,979,177, 120 genes, copy number 5–7 (broad region; genes not listed).
- chr18:24,218,300–25,352,190, 23 genes, copy number 5: RNU6-435P, MIR320C2, AC023983.1, AC023983.2, IMPACT, Y_RNA, AC007922.2, HRH4, AC007922.1, AC007922.4, AC007922.3, EIF4A3P1, LINC01915, RAC1P1, PPIAP57, AC018697.1, LINC01894, WBP2P1, AC104961.1, ZNF521, AC105114.2, AC105114.1, AC110603.1.
- chr18:29,518,259–47,630,848, 222 genes, copy number 7 (broad region; genes not listed).
- chr20:7,146,467–8,043,512, 11 genes, copy number 5 (within-gene range 3–5): LINC01428, AL080248.1, LINC01751, LINC01706, MIR8062, RN7SL547P, AL031679.1, AL021879.1, HAO1, TMX4, AL021396.1.
- chr20:10,435,305–24,226,013, 245 genes, copy number 6–7 (within-gene range 1–7) (broad region; genes not listed).
- chr20:24,445,391–26,251,546, 54 genes, copy number 6–9: GAPDHP53, SYNDIG1, AL157413.1, AL049594.1, AL035661.1, CST7, APMAP, RNU6-1257P, AL035661.2, ACSS1, AL080312.2, VSX1, AL080312.1, AL035252.2, AL035252.1, AL035252.5, ENTPD6, Y_RNA, AL035252.4, AL035252.3, AL121772.1, PYGB, AL121772.2, AL121772.3, ABHD12, PPIAP2, GINS1, NINL, RNU6ATAC17P, NANP, ZNF337-AS1, RN7SL594P, MED28P7, ZNF337, AL031673.1, AL390198.1, VN1R108P, FAM182B, BSNDP1, AL390198.2, BSNDP2, CFTRP1, LINC01733, FAM182A, AL078587.1, AL078587.2, AL450124.1, BSNDP3, NCOR1P1, AL391119.1, AL121904.2, MIR663AHG, AL121904.1, MIR663A.

Autosomal genes at a single copy (total copy number 1): 7,615. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
